Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADV, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADV-01A (Primary Tumor).

[page 1 of 2]
ICD O-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
Op 5/20/14

CLINICAL DIAGNOSIS: R/O HCC in S3

Specimen : Liver

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Left lateral sectionectomy

Organs: Liver (12.0 x 4.0 x 3.3 cm and 86.2 gm)

Lesion:

A well-defined multinodular pale tan firm and solid mass
(2.2 x 2.0 x 1.7 cm)

Gross type:

HCC: Multinodular confluent

Resection margin: Not involved grossly (safety margin: 2.2 cm)

Others:

Satellite nodule: No

Remaining parenchyma: Cirrhotic

Representative sections submitted

Gross photo: Present

Blocks

T1a,T1b,T1c,T1d,T2-3,TB, tumor mass x 7

L,NB, liver parenchyma x 2

MICROSCOPIC:

Hepatocellular carcinoma: Yes

The worst differentiation III

The major differentiation II

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: Yes (10 %)

Fibrous capsule formation: Partial capsule

Septum formation: No

Surgical resection margin invasion: No/ safety margin (2.2 cm)

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: No

Intrahepatic metastasis: Unknown

Multicentric occurrence: Unknown

NOT reported. Gross:

NOT reported. Gross:

Stomach, body, dissection, tubular adenoma, high grade, dysplasia

Stomach, prepylorus, scopic, chronic gastritis

[page 2 of 2]
Stomach, antrum, scopic, chronic gastritis, H. pylori, associated

Liver, legy, ectomy, hepatocellular carcinoma, moderately differentiated, cirrhosis, steatosis

T56000, legy, P10, M81703, moderately differentiated, M49500, M50080

DIAGNOSIS:

Liver, segment 3, left lateral sectionectomy:

Hepatocellular carcinoma, moderately differentiated

Cirrhosis, mixed

Steatosis, mild

Suggestion :

Source: NCI Genomic Data Commons file 51a0a288-5387-4aec-b2f4-cb7c2919c76e (TCGA-DD-AADV.750CC634-8874-488C-B20D-6B636978156A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).